Surgical pathology report (de-identified scan), TCGA case TCGA-HW-7486, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-7486-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Location:

Service:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right frontal brain tumor.

Specimens Submitted:

1: SP: Right inferior frontal brain tumor

2: SP: Right inferior frontal brain tumor # 2

3: SP: Right inferior frontal brain tumor # 3

DIAGNOSIS:

1. BRAIN, RIGHT INFERIOR FRONTAL LOBE; BIOPSY:
- NON- DIAGNOSTIC MATERIAL

2,3. BRAIN, RIGHT INFERIOR FRONTAL LOBE; RESECTION:
- OLIGODENDROGLIOMA, WHO GRADE II
- MATERIAL WILL BE SENT FOR 1p/19q AND MGMT ASSESSMENT.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain

Comment

RECUT

MIB-1 (Ki-67)

IMM RECUT

MIB-1 (Ki-67)

RECUT

NEG CONT

Gross Description:

1. The specimen is submitted fresh for frozen section, labeled "right inferior of frontal brain tumor" and consists of multiple fragments of red-tan soft tissue measuring 1.5 x 1.0 x 0.3 cm in aggregate. A smear preparation is made and the remaining specimen is entirely submitted for frozen section.

Summary of sections:

FSCA - frozen section control A

FSCB - frozen section control B

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

2). The specimen is received fresh for frozen section consultation, labeled "Right inferior frontal brain tumor number two" and consists of a 1 x 0.5 x 0.5 cm fragment of soft tissue which is entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

3). The specimen is received fresh labeled, "right inferior frontal brain tumor #3, fresh and sterile", and consists of multiple pieces of gray-tan to red-pink friable soft tissue measuring 3.3 x 2.5 x 1.2 cm in aggregate. The specimen is entirely submitted.

Summary of sections:

U -- undesignated

Summary of Sections:

Part 1: SP: Right inferior frontal brain tumor

Block	Sect. Site	PCs
1	FSCA	1
1	FSCB	1

Part 2: SP: Right inferior frontal brain tumor # 2

Block	Sect. Site	PCs
1	fsc	1

Part 3: SP: Right inferior frontal brain tumor # 3

Block	Sect. Site	PCs
3	U	30

Procedures/Addenda:

Addendum

Date Ordered:

Date Complete:

Date Reported:

Status: Signed Out

Addendum Diagnosis

MIB-1 LABELING INDEX DOES NOT EXCEED 4%.

MATERIAL SENT FOR 1p/19q AND MGMT ASSESSMENT.

Intraoperative Consultation:

1. SP: Right inferior frontal brain tumor. INCREASED GLIAL CELLULARITY, BUT CANNOT DIAGNOSE GLIOMA IN THIS MATERIAL.
PERMANENT DIAGNOSIS: SAME

2. SP: Right inferior frontal brain tumor # 2. GLIOMA, POSSIBLY OLIGODENDROGLIOMA.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 2fdcf43a-c289-49ef-a905-08a64deed14c (TCGA-HW-7486.D98D840C-4ACF-4312-98B5-C9F35F3517F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).